Gene-level copy-number profile of tumor specimen ALCH-ADPQ-TTP1-A from ALCHEMIST case ALCH-ADPQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 80.8 years (29,500 days).
Specimen ALCH-ADPQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bc93af99-5467-4f19-a9c2-b2f9cc2a127e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADPQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/76c2b9dc-81d8-48fc-b9d4-4d8b273f4185

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 416; copy number 2: 20,885; copy number 3: 22,804; copy number 4: 8,324; copy number 5: 3,830; copy number 6: 479; copy number 7: 1,207; copy number 8: 232; copy number 9: 62; copy number 10: 4; copy number 11: 20; copy number 13: 2; copy number 15: 10; copy number 19: 51; copy number 20: 10; copy number 25: 9; copy number 33: 12; copy number 42: 11; copy number 50: 14; copy number 51: 9.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr9:38,452,782–38,454,070, 1 gene: ARMC8P1.
- chr10:48,009,873–48,031,640, 1 gene: AGAP12P.
- chr14:105,467,793–105,470,617, 1 gene (within-gene range 0–1): AL928654.2.
- chr14:105,486,317–105,492,267, 2 genes (within-gene range 0–1): CRIP1, AL928654.3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,653 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:46,816,697–68,980,980, 345 genes, copy number 7–15 (within-gene range 7–21) (broad region; genes not listed).
- chr3:129,087,569–130,035,539, 38 genes, copy number 8: RAB43, ISY1-RAB43, AC108673.2, ISY1, AC108673.3, CNBP, RPS27P12, COPG1, MIR6826, AC137695.3, HMCES, H1-10, H1-10-AS1, NUP210P3, AC137695.1, AC137695.2, AL449212.1, RPL32P3, SNORA7B, EFCAB12, MBD4, IFT122, RHO, H1-8, PLXND1, RN7SL752P, AC023162.1, TMCC1, RNY3P13, U6, AC083799.1, TMCC1-AS1, AC083906.3, TRH, AC083906.1, AC083906.2, OR7E129P, OR7E21P.
- chr3:130,081,831–195,584,033, 1,054 genes, copy number 7–8 (broad region; genes not listed).
- chr3:195,746,765–198,123,232, 93 genes, copy number 8 (broad region; genes not listed).
- chr11:44,539,778–46,739,506, 60 genes, copy number 19–25: AC010768.3, CD82, AC010768.1, AC010768.2, RPL34P22, AC104010.1, LINC02704, TSPAN18-AS1, TSPAN18, TP53I11, LINC02685, PRDM11, AC103681.2, SYT13, AC103681.1, LINC02696, LINC02687, AC103855.3, AC018716.2, AC018716.1, AC103855.2, AC103855.4, AC103855.1, CHST1, AC087442.1, MIR7154, AC044839.1, AC044839.2, LINC02690, LINC02716, SLC35C1, AC044839.3, CRY2, MAPK8IP1, AC068385.1, C11orf94, PEX16, LARGE2, PHF21A, AC024475.1, AC024475.3, AC024475.2, LINC02710, AC116021.1, LINC02489, CREB3L1, DGKZ, MIR4688, MDK, CHRM4, AMBRA1, AC024293.1, MIR3160-1, MIR3160-2, AC127035.1, HARBI1, ATG13, ARHGAP1, ZNF408, F2.
- chr11:68,460,731–70,436,584, 56 genes, copy number 20–51: PPP6R3, NDUFA3P2, AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr16:32,903,442–32,946,392, 4 genes, copy number 10: IGHV3OR16-15, IGHV3OR16-6, AC142086.6, AC142086.3.
- chr21:44,107,373–44,131,181, 1 gene, copy number 8: PWP2.
- chr21:44,172,169–44,194,338, 2 genes, copy number 13: AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 416. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
